Gene-level copy-number profile of tumor specimen HCM-SANG-0533-C20-01A-01D-A80T-32 from HCMI case HCM-SANG-0533-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0533-C20-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5299f9df-4777-44db-9826-66ed8c633e09.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0533-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/96583a2d-724e-4c65-85bd-4f4ad74d9bca

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,721; copy number 1: 23,884; copy number 2: 27,910; copy number 3: 4,023; copy number 4: 595; copy number 6: 27; copy number 8: 61; copy number 10: 38; copy number 12: 34; copy number 18: 13; copy number 20: 78; copy number 39: 16.

Homozygous deletions (total copy number 0; autosomes only): 1,721 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:74,026,015–79,522,203, 84 genes (broad region; genes not listed).
- chr1:80,373,364–80,646,791, 6 genes: AL606519.1, HNRNPA1P64, AL596276.1, AL596276.2, AL136234.1, LINC01781.
- chr1:103,414,879–121,580,524, 395 genes (broad region; genes not listed).
- chr2:235,494,043–236,131,800, 6 genes (within-gene range 0–2): AGAP1, AGAP1-IT1, AC064874.1, TMSB10P1, RNU7-127P, RN7SL204P.
- chr3:19,879,472–20,012,606, 7 genes: EFHB, HSPA8P18, RAB5A, PP2D1, RNU4-85P, SAP18P3, RPL39P18.
- chr3:59,747,277–61,251,459, 8 genes: FHIT, AC093418.1, AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.
- chr3:90,261,414–90,261,708, 1 gene: HSPE1P19.
- chr5:60,021,249–60,033,020, 1 gene (within-gene range 0–2): AC034234.1.
- chr6:21,485,896–21,523,783, 2 genes: LINC00581, AL512380.1.
- chr8:89,412,621–89,833,564, 5 genes: KRT8P4, AF117829.1, RIPK2, COX6B1P6, AF117829.2.
- chr10:79,703,227–79,714,681, 1 gene (within-gene range 0–2): NUTM2B.
- chr18:45,034–80,247,514, 1,199 genes (broad region; genes not listed).
- chr20:14,547,184–14,547,623, 1 gene (within-gene range 0–1): RNF11P2.
- chr20:14,757,563–14,758,056, 1 gene (within-gene range 0–1): RPS10P2.
- chr20:14,933,843–15,280,873, 4 genes (within-gene range 0–1): AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 267 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:37,084,992–37,406,836, 1 gene, copy number 12 (within-gene range 2–12): ACACA.
- chr17:37,375,985–42,440,259, 266 genes, copy number 6–39 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 23,884. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
